CPTAC case C3L-00161 — Uterus, NOS — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Uterus, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/32fc9aa9-a821-47cc-974b-5bcab2946b7d

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Year of birth: 1970; Vital status: Alive; Country of birth: United States.

Diagnoses (1)
1. Endometrioid adenocarcinoma, NOS: ICD-O-3 morphology code: 8380/3; Tissue or organ of origin: Uterus, NOS; Site of resection or biopsy: Endometrium; Age at diagnosis: 46.2 years (16,864 days); Year of diagnosis: 2016; AJCC staging edition: 7th; AJCC clinical M: MX; AJCC pathologic T: T1b; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Residual disease: RX; Last known disease status: With tumor; Days to last known disease status: 1,775 days (4.9 years); Progression or recurrence: yes; Days to recurrence: 1,369 days (3.7 years); Days to last follow up: 1,775 days (4.9 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 7 cm; Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 0; Margin status: Indeterminate.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (6 entries)
- Days to follow up: 438 days (1.2 years); Disease response: Tumor Free; Karnofsky performance status: 80; ECOG performance status: 1.
- Days to follow up: 718 days (2.0 years); Karnofsky performance status: 80; ECOG performance status: 1.
- Days to follow up: 1,176 days (3.2 years); Karnofsky performance status: 80; ECOG performance status: 1.
- Days to follow up: 1,453 days (4.0 years); Disease response: With Tumor; ECOG performance status: 1.
- Days to follow up: 1,775 days (4.9 years); Disease response: With Tumor; ECOG performance status: 3.
- Days to follow up: 1,775 days (4.9 years); Disease response: Progressive Disease; Progression or recurrence: Yes; Days to recurrence: 1,369 days (3.7 years); ECOG performance status: 3.

Other clinical attributes
- Weight: 164.2 kg; Height: 154.94 cm; BMI: 68.39.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (8 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-00161-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 118 mg; Time between excision and freezing: 28 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-00161-21: Section location: Posterior endometrium; Percent tumor nuclei: 80; Percent necrosis: 2.
- Sample C3L-00161-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 147 mg; Time between excision and freezing: 28 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-00161-22: Section location: Posterior endometrium; Percent tumor nuclei: 80; Percent necrosis: 0.
- Sample C3L-00161-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 0.093 mg.
- Sample C3L-00161-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 0.173 mg.
- Sample C3L-00161-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 0.127 mg.
- Sample C3L-00161-12: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Time between excision and freezing: 28 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-00161-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
- Sample C3L-00161-32: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC).
